Somatic mutation profile of tumor specimen HCM-BROD-0689-C71-02A (aliquot HCM-BROD-0689-C71-02A-11D-A83U-36) from HCMI case HCM-BROD-0689-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 63.1 years (23,030 days).
Specimen HCM-BROD-0689-C71-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c0bc759b-3be9-4171-be44-31d002bb85fe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0689-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0689-C71-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6326a17e-c1e0-4140-b440-e4d4e93d0c6f

The open-access MAF lists 74 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 19, Frame Shift Del 6, Nonsense Mutation 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 174/401 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs786204859, CD110173, CM983501, COSV64288670, COSV64294671; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 125/371 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AMOT | c.2347C>T p.R783W (on ENST00000371959 / NM_001113490.1; = p.R374W on NM_133265.3) | Missense Mutation (SNP) | VAF 64/1026 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1351392465; called by muse, mutect2
- BDH1 | c.232A>G p.K78E | Missense Mutation (SNP) | VAF 99/628 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.007); catalogued as rs773056463; called by muse, mutect2, varscan2
- CCNDBP1 | c.735del p.A246Rfs*3 | Frame Shift Del (DEL) | VAF 82/466 reads (18%) | catalogued as COSV55746601; called by mutect2, pindel, varscan2
- GRM1 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 64/360 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51372504; called by muse, mutect2, varscan2
- LYPD2 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 166/628 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs1160940176; called by muse, varscan2
- MAOB | c.797C>T p.P266L | Missense Mutation (SNP) | VAF 67/381 reads (18%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.66); catalogued as COSV65204342; called by muse, mutect2, varscan2
- MUC5B | c.8486C>A p.T2829N | Missense Mutation (SNP) | VAF 49/1117 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs1242522249; called by muse, mutect2
- NAV3 | c.5024G>T p.S1675I | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV99888867; called by muse, mutect2, varscan2
- PRAMEF8 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 230/961 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.048); catalogued as rs1367743735; called by muse, mutect2, varscan2
- PRKDC | c.10127G>A p.G3376D | Missense Mutation (SNP) | VAF 168/533 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as rs1272452350; called by muse, mutect2, varscan2
- PSMD10 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 148/529 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs1362416960; called by muse, mutect2, varscan2
- RFC3 | c.1027T>A p.Y343N | Missense Mutation (SNP) | VAF 63/323 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66296590; called by muse, mutect2, varscan2
- SLC35D2 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 14/412 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1335791975; called by muse, mutect2
- SLC7A14 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 204/504 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs756436577, COSV51578448; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBXT | c.626A>C p.K209T | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV51616339; called by muse, mutect2, varscan2
- TNFRSF11B | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 150/532 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs774691067; called by muse, mutect2, varscan2
- TRPC5 | c.2168del p.R723Nfs*6 | Frame Shift Del (DEL) | VAF 53/282 reads (19%) | catalogued as COSV53283720; called by mutect2, varscan2
- UGT1A1 | c.25C>T p.R9C | Missense Mutation (SNP) | VAF 104/436 reads (24%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs370790922; called by muse, varscan2
- WNK3 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 12/456 reads (3%) | catalogued as COSV63614265, COSV63615060; called by muse, mutect2
- APOB | c.10471T>G p.S3491A | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- BCHE | c.1334T>A p.F445Y | Missense Mutation (SNP) | VAF 78/602 reads (13%) | SIFT tolerated (0.95); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CACNG1 | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 25/365 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.025); called by muse, mutect2
- CENPE | c.5625G>T p.Q1875H | Missense Mutation (SNP) | VAF 16/262 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CIZ1 | c.1441G>A p.V481I | Missense Mutation (SNP) | VAF 114/660 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- COL5A1 | c.4396C>G p.P1466A | Missense Mutation (SNP) | VAF 66/449 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DOT1L | c.3565C>T p.P1189S | Missense Mutation (SNP) | VAF 32/404 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.085); called by muse, mutect2
- EIF4G1 | c.1069G>T p.E357* (on ENST00000346169 / NM_198241.3; = p.E161* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 94/666 reads (14%) | called by muse, mutect2, varscan2
- EYS | c.2567T>C p.L856P | Missense Mutation (SNP) | VAF 128/473 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HIVEP2 | c.4802A>G p.H1601R | Missense Mutation (SNP) | VAF 20/621 reads (3%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- INTS1 | c.1566G>T p.E522D | Missense Mutation (SNP) | VAF 71/396 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- IP6K3 | c.67_77del p.H23Gfs*9 | Frame Shift Del (DEL) | VAF 64/571 reads (11%) | called by mutect2, pindel, varscan2
- LINGO2 | c.305A>T p.N102I | Missense Mutation (SNP) | VAF 38/614 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.52); called by muse, mutect2
- MUC16 | c.34462A>G p.T11488A | Missense Mutation (SNP) | VAF 97/448 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- NECTIN2 | c.236A>C p.H79P | Missense Mutation (SNP) | VAF 159/676 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NKAPL | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 77/406 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OR10J1 | c.125A>G p.N42S | Missense Mutation (SNP) | VAF 65/357 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4Q3 | c.713T>C p.F238S | Missense Mutation (SNP) | VAF 18/412 reads (4%) | SIFT tolerated (1); PolyPhen possibly damaging (0.761); called by muse, mutect2
- OR56A1 | c.449T>C p.F150S | Missense Mutation (SNP) | VAF 29/348 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2
- PIK3CB | c.2969A>G p.Y990C | Missense Mutation (SNP) | VAF 22/712 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPFIBP2 | c.2429A>C p.K810T | Missense Mutation (SNP) | VAF 48/197 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SH3GL3 | c.772A>G p.R258G | Missense Mutation (SNP) | VAF 26/567 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- SLCO5A1 | c.1720G>A p.G574R | Missense Mutation (SNP) | VAF 52/724 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SNX18 | c.1494T>A p.D498E | Missense Mutation (SNP) | VAF 117/581 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ST6GALNAC4 | c.10C>G p.P4A | Missense Mutation (SNP) | VAF 186/526 reads (35%) | PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMPPE | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 90/560 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPC5 | c.2167del p.R723Dfs*6 | Frame Shift Del (DEL) | VAF 61/398 reads (15%) | called by mutect2*, pindel, varscan2*
- TTPA | c.139_150delinsT p.L47Ffs*25 | Frame Shift Del (DEL) | VAF 100/892 reads (11%) | called by pindel, varscan2*
- UBR3 | c.3338A>G p.D1113G | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- UGT2B4 | c.551G>T p.S184I | Missense Mutation (SNP) | VAF 44/334 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.47); called by muse, mutect2, varscan2
- USP47 | c.2418del p.F806Lfs*58 (on ENST00000399455 / NM_001372095.1; = p.F718Lfs*58 on NM_017944.4 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 56/392 reads (14%) | called by mutect2, pindel, varscan2
- ZFAND4 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 32/220 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF280A | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.029); called by muse, mutect2
- BRF1 | c.15G>T p.V5= | Silent (SNP) | VAF 40/604 reads (7%) | called by muse, mutect2
- CHPF | c.2127G>A p.E709= | Silent (SNP) | VAF 24/744 reads (3%) | called by muse, mutect2
- CNTN6 | c.495C>T p.Y165= | Silent (SNP) | VAF 63/310 reads (20%) | catalogued as rs114806249; called by muse, mutect2, varscan2
- EIF4G1 | c.1068G>T p.V356= (on ENST00000346169 / NM_198241.3; = p.V160= on NM_004953.5) | Silent (SNP) | VAF 90/628 reads (14%) | called by mutect2, varscan2
- FAM170B | c.201G>A p.G67= | Silent (SNP) | VAF 79/516 reads (15%) | catalogued as rs1327006521, COSV61254054; called by muse, varscan2
- FLG | c.7341A>T p.R2447= | Silent (SNP) | VAF 18/392 reads (5%) | called by muse, mutect2
- FLNC | c.2838T>C p.Y946= | Silent (SNP) | VAF 70/354 reads (20%) | catalogued as rs769390195; called by muse, mutect2, varscan2
- ITGA5 | c.1056T>C p.D352= | Silent (SNP) | VAF 91/519 reads (18%) | called by muse, mutect2, varscan2
- OR5F1 | c.330C>T p.T110= | Silent (SNP) | VAF 66/387 reads (17%) | catalogued as rs573086848, COSV53545530, COSV99558547; called by muse, mutect2, varscan2
- PRRT4 | c.1626G>T p.P542= | Silent (SNP) | VAF 249/937 reads (27%) | catalogued as rs745375588; called by muse, mutect2, varscan2
- RGS12 | c.810G>A p.S270= | Silent (SNP) | VAF 120/520 reads (23%) | catalogued as rs138890505; called by muse, mutect2, varscan2
- SH2D3C | c.543C>T p.S181= (on ENST00000314830 / NM_170600.3; = p.S24= on NM_005489.4) | Silent (SNP) | VAF 52/360 reads (14%) | catalogued as rs539496048; called by muse, mutect2, varscan2
- SPAM1 | c.486T>C p.D162= | Silent (SNP) | VAF 39/315 reads (12%) | called by muse, mutect2, varscan2
- SPATA31A1 | c.3945A>C p.V1315= | Silent (SNP) | VAF 40/1074 reads (4%) | called by muse, mutect2
- TRAPPC8 | c.1848G>A p.Q616= | Silent (SNP) | VAF 77/458 reads (17%) | catalogued as rs140670473; called by muse, mutect2, varscan2
- UGT2B17 | c.996C>A p.I332= | Silent (SNP) | VAF 19/74 reads (26%) | called by muse, mutect2, varscan2
- VCAN | c.2445A>G p.L815= | Silent (SNP) | VAF 25/476 reads (5%) | catalogued as rs1304533964; called by muse, mutect2
- WNK3 | c.1146T>A p.I382= | Silent (SNP) | VAF 12/456 reads (3%) | called by muse, mutect2
- ZNF74 | c.1467G>C p.V489= | Silent (SNP) | VAF 144/683 reads (21%) | called by muse, mutect2, varscan2
- CXorf56 | c.243-1006G>T | Intron (SNP) | VAF 99/346 reads (29%) | catalogued as COSV100233397; called by muse, mutect2, varscan2
